Somatic mutation profile of tumor specimen TCGA-HT-8107-01A (aliquot TCGA-HT-8107-01A-13D-2395-08) from TCGA case TCGA-HT-8107, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 62.6 years (22,880 days).
Specimen TCGA-HT-8107-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec942e24-a1a5-40c8-af0c-e9fa26a40645.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8107-10A (Blood Derived Normal), aliquot TCGA-HT-8107-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d105aee-3966-43e1-a4e8-4f7c6c055d42

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 23/158 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
